Somatic mutation profile of tumor specimen TCGA-17-Z003-01A (aliquot TCGA-17-Z003-01A-01W-0746-08) from TCGA case TCGA-17-Z003, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f3ed15f-ea3a-4f62-b5dd-4d9af15beec9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z003-11A (Solid Tissue Normal), aliquot TCGA-17-Z003-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19524185-3ec6-4956-996a-c88422958a73

The open-access MAF lists 256 somatic variants for this specimen: 192 protein-altering or splice-affecting, 54 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 54, Nonsense Mutation 13, Frame Shift Del 5, Intron 5, Splice Site 5, Frame Shift Ins 2, 5'Flank 2, RNA 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201215222; called by muse, mutect2
- ADGRL3 | c.2138T>C p.L713P (on ENST00000506720 / NM_001322402.2; = p.L645P on NM_015236.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765594098; called by muse, mutect2
- AP002512.3 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs142752109; called by muse, mutect2, varscan2
- ARHGAP32 | c.5579G>A p.S1860N (on ENST00000310343 / NM_001378025.1; = p.S1511N on NM_014715.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1377304727; called by muse, mutect2, varscan2
- ATP13A4 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs779343854; called by muse, mutect2
- BCAS3 | c.2420G>C p.R807P (on ENST00000390652 / NM_001353144.2; = p.R792P on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV66778270; called by muse, mutect2, varscan2
- BRINP1 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.381); catalogued as COSV99775109; called by muse, mutect2
- CCDC88A | c.3217G>C p.E1073Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV99710076; called by muse, mutect2, varscan2
- CEP350 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1279961552; called by muse, mutect2, varscan2
- CEP70 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1214693592; called by muse, mutect2, varscan2
- CFAP92 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs770501437; called by muse, mutect2, varscan2
- CMYA5 | c.5117A>T p.E1706V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as rs1165854720; called by muse, mutect2, varscan2
- COL2A1 | c.2410-1G>A p.X804_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV61535525; called by muse, mutect2, varscan2
- CSMD3 | c.5215C>T p.L1739F (on ENST00000297405 / NM_001363185.1; = p.L1635F on NM_052900.3) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52124901; called by muse, mutect2, varscan2
- CYP4F12 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs201412557; called by muse, mutect2
- DOCK4 | c.3662A>T p.Y1221F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs200606456; called by muse, mutect2, varscan2
- DRP2 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs747128168; called by muse, mutect2, varscan2
- DSG1 | c.2957C>A p.A986D | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99935947; called by muse, mutect2, varscan2
- EDARADD | c.623G>C p.R208P (on ENST00000334232 / NM_145861.4; = p.R198P on NM_080738.4) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs376731607, COSV62061445; called by muse, mutect2, varscan2
- FAM47A | c.535C>G p.P179A | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.167); catalogued as COSV60494070; called by muse, mutect2, varscan2
- FAM47B | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV61452324; called by muse, mutect2, varscan2
- FAT1 | c.13156T>C p.S4386P | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752679483; called by muse, mutect2, varscan2
- FCRL1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs149142723, COSV63826848; called by muse, mutect2, varscan2
- GBA3 | c.668C>G p.S223* | Nonsense Mutation (SNP) | VAF 26/191 reads (14%) | catalogued as COSV101545472; called by muse, mutect2, varscan2
- GGCX | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.078); catalogued as rs1331313686; called by muse, mutect2
- GOLGA3 | c.1590C>A p.D530E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); catalogued as rs371271083; called by muse, mutect2, varscan2
- HYAL4 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs199541453; called by mutect2, varscan2
- IFI16 | c.1190A>T p.N397I | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs748916757, COSV55539577; called by muse, mutect2, varscan2
- IGF2 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV56100058, COSV56100259; called by muse, mutect2
- IL25 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as rs772921037; called by muse, mutect2, varscan2
- ITPRID1 | c.2800C>A p.Q934K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs1335454160; called by muse, mutect2, varscan2
- KCNT2 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV54103805; called by muse, mutect2, varscan2
- KMT2C | c.2194del p.L732Ffs*5 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as COSV51434597; called by mutect2, varscan2
- KRT26 | c.609T>A p.C203* | Nonsense Mutation (SNP) | VAF 22/136 reads (16%) | catalogued as rs1051587212; called by muse, mutect2, varscan2
- LAMA4 | c.2667+1G>A p.X889_splice (on ENST00000230538 / NM_001105206.3; = p.X882_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as rs1373538377; called by muse, mutect2, varscan2
- LRP1B | c.13183G>T p.D4395Y | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.915); catalogued as rs1271216199, COSV67190190; called by muse, mutect2
- MAGEB6B | c.1180G>C p.A394P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69689822; called by muse, mutect2, varscan2
- MAGEC1 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1331375349; called by muse, mutect2
- MAGEC2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV55999437; called by muse, mutect2, varscan2
- MAP3K3 | c.474dup p.E159Rfs*26 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | catalogued as rs1208446998; called by pindel, varscan2
- MSH6 | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267608089, CM136610, COSV52277892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK10 | c.2059A>G p.T687A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1273255269; called by muse, mutect2, varscan2
- NRIP1 | c.41A>T p.D14V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59656137, COSV59660286; called by muse, mutect2, varscan2
- NRXN1 | c.1801C>A p.P601T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as COSV100454510; called by muse, mutect2, varscan2
- OR2D3 | c.987G>T p.R329S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1350712074; called by muse, mutect2
- OR2T34 | c.781T>C p.F261L | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs202022208; called by muse, mutect2, varscan2
- OR4A15 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.067); catalogued as COSV59035140; called by muse, mutect2, varscan2
- OR4A16 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs765052516; called by muse, varscan2
- OR5T3 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV57379529; called by muse, mutect2, varscan2
- OR8B4 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as COSV62069409; called by muse, mutect2
- PCDH15 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99054655; called by muse, mutect2, varscan2
- PCDH15 | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57290777, COSV57399900; called by muse, mutect2
- PEAR1 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs779189362; called by muse, mutect2, varscan2
- PGBD2 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as rs373201298; called by muse, mutect2, varscan2
- PHF20 | c.1169A>T p.D390V | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs777301538; called by muse, mutect2, varscan2
- PIGO | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs763191841, COSV53055565; called by muse, mutect2, varscan2
- PKHD1L1 | c.417C>T p.N139= | Splice Region (SNP) | VAF 17/124 reads (14%) | catalogued as rs369855402; called by muse, mutect2, varscan2
- PRELP | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs56086342; called by muse, mutect2, varscan2
- RAVER2 | c.503T>C p.I168T | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs572662102; called by muse, mutect2
- RLF | c.3245C>T p.S1082L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.236); catalogued as COSV101035641; called by muse, mutect2, varscan2
- SATB2 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | catalogued as COSV53489016; called by muse, mutect2, varscan2
- SCN7A | c.4190T>A p.F1397Y | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs189400534; called by muse, mutect2
- SLC27A6 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1263953542, COSV52479784; called by muse, mutect2, varscan2
- SNAI2 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs748128814; called by muse, mutect2, varscan2
- SNX29 | c.1763A>G p.Y588C | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1173393708; called by muse, mutect2
- STAG1 | c.3175G>C p.D1059H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV99365196; called by muse, mutect2, varscan2
- TCERG1L | c.1168C>A p.R390S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as rs200282379, COSV64047185; called by muse, mutect2, varscan2
- TEX13A | c.1039G>T p.G347W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.524); catalogued as rs1556172822, COSV61145507; called by muse, mutect2, varscan2
- TNR | c.1475G>T p.R492L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54872423, COSV54884485; called by muse, mutect2, varscan2
- TPO | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777937878, COSV61102562; called by muse, mutect2
- TREM1 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV99776130; called by muse, mutect2, varscan2
- TRPV2 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs1170132643; called by muse, mutect2, varscan2
- TSPEAR | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1425457705, COSV59957782, COSV59960387; called by muse, mutect2, varscan2
- TTN | c.33614C>A p.P11205H (on ENST00000591111; = p.P10278H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | PolyPhen possibly damaging (0.891); catalogued as rs746552848; called by muse, mutect2
- TTN | c.12881C>G p.P4294R (on ENST00000591111; = p.P4248R on NM_003319.4) | Missense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as rs1468424407, COSV100626207; called by muse, mutect2, varscan2
- ZNF582 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs571710209; called by muse, mutect2, varscan2
- A2M | c.2168T>A p.V723D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAT2 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.015); called by muse, mutect2
- ACP6 | c.804del p.M269Cfs*2 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel, varscan2
- ADAM9 | c.1068T>A p.N356K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ADGRG4 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADGRV1 | c.8574C>G p.I2858M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AKNAD1 | c.1366T>C p.F456L | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ALG10B | c.881T>G p.F294C | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ANKEF1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- ANO3 | c.2438T>A p.L813H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP4E1 | c.758A>C p.Q253P | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- APBB1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- APC | c.4811C>T p.P1604L | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP32 | c.1961A>T p.K654M (on ENST00000310343 / NM_001378025.1; = p.K305M on NM_014715.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP9A | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- BAAT | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BFSP2 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2
- BTK | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C2orf78 | c.309C>G p.S103R | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC113 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CDH6 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CEACAM20 | c.95T>A p.L32H | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2
- CMYA5 | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CNKSR1 | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- COL11A2 | c.1019del p.P340Lfs*42 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- CRISP1 | c.335G>T p.W112L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.4220T>C p.L1407P (on ENST00000297405 / NM_001363185.1; = p.L1303P on NM_052900.3) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.9422A>T p.K3141I | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- CYP1B1 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CYP2B6 | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by mutect2, varscan2
- DCDC1 | c.3789G>C p.W1263C (on ENST00000597505 / NM_001367979.1; = p.W370C on NM_020869.3) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2
- DMRTB1 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ERC1 | c.3202A>C p.T1068P (on ENST00000360905 / NM_178040.4; = p.T1040P on NM_178039.4) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- FAM135B | c.3682C>A p.L1228I | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAT1 | c.5529del p.H1844Tfs*22 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- FERMT2 | c.1273+1del p.X425_splice | Splice Site (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- FN1 | c.2633T>A p.I878N | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FREM1 | c.6481C>A p.Q2161K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- FSHR | c.1755G>T p.M585I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- GARS1 | c.702A>C p.E234D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- GASK1B | c.1274T>A p.L425* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- GCDH | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- GLDN | c.1550T>C p.L517P | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA4 | c.261T>A p.Y87* | Nonsense Mutation (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2
- GRIK2 | c.221C>G p.T74S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- HDGF | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 102/407 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- HOXD1 | c.780C>G p.I260M | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- KCND2 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCNK10 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- KCNS3 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21A | c.1469+2T>C p.X490_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- KIF5C | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDLRAD1 | c.300dup p.T101Hfs*10 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- LHX9 | c.58A>T p.M20L | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LMX1A | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- LRRC4C | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC1 | c.1183A>G p.R395G | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, varscan2
- MAGEC2 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- MAOA | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MID1 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MMS22L | c.1822G>T p.V608L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MTMR6 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MTNR1A | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2
- MUC16 | c.16316C>A p.S5439Y | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NAV3 | c.2278G>T p.G760C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- NME8 | c.1287C>A p.N429K | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOX3 | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- NPHS1 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- NUP107 | c.702A>T p.L234F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- NUP133 | c.996A>T p.E332D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OGFOD1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13A1 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- OR2D3 | c.986G>T p.R329M | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- OR5AP2 | c.447G>C p.L149F | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.038); called by muse, mutect2
- OR6C4 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- PASK | c.3835G>C p.A1279P | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PAX8 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCIF1 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDGFRA | c.339A>C p.E113D | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PHF3 | c.4936A>G p.I1646V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PLCB3 | c.1837A>T p.K613* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- POLL | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- POMGNT1 | c.1432T>C p.W478R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN20 | c.889A>T p.I297F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- RBL1 | c.896+1G>C p.X299_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- RFC2 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS2 | c.3658G>C p.G1220R | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUNX1T1 | c.1449G>T p.R483S (on ENST00000265814 / NM_001198628.1; = p.R456S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.10769G>C p.G3590A (on ENST00000389232; = p.G3591A on NM_001036.6) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2
- SCN1A | c.2372C>A p.P791Q (on ENST00000303395 / NM_001202435.3; = p.P780Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SEMG2 | c.793A>G p.K265E | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SHROOM4 | c.552C>A p.N184K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, varscan2
- SLC17A3 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- SLC24A2 | c.1624G>C p.A542P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC1B | c.3082A>G p.K1028E | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2
- SORCS1 | c.1736G>T p.R579I | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SPAM1 | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2
- SPARC | c.767G>C p.R256P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTA1 | c.6652G>T p.D2218Y | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPTA1 | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2
- SPTBN4 | c.5152G>A p.E1718K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STAB2 | c.756T>A p.C252* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- TET2 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- TLK1 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TOX2 | c.1069C>G p.R357G (on ENST00000358131 / NM_001098798.2; = p.R333G on NM_032883.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRANK1 | c.2391A>T p.E797D | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- TTN | c.66700A>G p.T22234A (on ENST00000591111; = p.T14810A on NM_003319.4) | Missense Mutation (SNP) | VAF 17/169 reads (10%) | PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TTN | c.33613C>A p.P11205T (on ENST00000591111; = p.P10278T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | PolyPhen benign (0.306); called by muse, mutect2
- TWNK | c.1920G>C p.K640N | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TXNDC11 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ULBP3 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- VGLL1 | c.526A>T p.R176* | Nonsense Mutation (SNP) | VAF 51/138 reads (37%) | called by muse, mutect2, varscan2
- ZNF140 | c.1149del p.K383Nfs*108 | Frame Shift Del (DEL) | VAF 15/110 reads (14%) | called by mutect2, pindel, varscan2
- ZNF181 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF514 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ADAM2 | c.387C>T p.P129= | Silent (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- ANKRD12 | c.3615C>T p.S1205= | Silent (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- ASB4 | c.634C>T p.L212= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57947050; called by muse, mutect2, varscan2
- BCAN | c.1917T>C p.G639= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2
- C5AR1 | c.783G>A p.T261= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs370056891; called by mutect2, varscan2
- C8A | c.906G>A p.K302= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs377378202; called by muse, mutect2, varscan2
- CACNA2D1 | c.1173A>G p.Q391= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1335302864; called by muse, mutect2, varscan2
- CNTN1 | c.1296G>C p.V432= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- DACH2 | c.399G>A p.G133= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- DEAF1 | c.1278G>T p.L426= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1455077962; called by muse, mutect2, varscan2
- EFHC1 | c.447A>T p.I149= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- ELMO1 | c.1560C>A p.S520= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV60297105; called by muse, mutect2, varscan2
- ERICH3 | c.2943C>A p.A981= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- FAM135B | c.3681C>A p.V1227= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV99425100; called by muse, mutect2, varscan2
- FLG | c.10854A>C p.A3618= | Silent (SNP) | VAF 22/476 reads (5%) | called by muse, mutect2
- GP2 | c.456G>T p.V152= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- HAVCR1 | c.759A>T p.S253= | Silent (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- HOOK1 | c.1293A>G p.R431= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- KCNH5 | c.1476A>G p.L492= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- KIF13B | c.2466C>T p.I822= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- LAMA2 | c.7641A>G p.G2547= | Silent (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- LRP2 | c.9690G>T p.V3230= | Silent (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- LY6D | c.120C>A p.A40= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- MYH1 | c.3900A>T p.T1300= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- NANP | c.618A>G p.T206= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs765547142; called by mutect2, varscan2
- NCOA6 | c.1104G>T p.T368= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- NHSL2 | c.813C>T p.H271= (on ENST00000510661; = p.H637= on NM_001013627.2) | Silent (SNP) | VAF 6/45 reads (13%) | called by mutect2, varscan2
- NNT | c.378C>G p.V126= | Silent (SNP) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- OBSCN | c.4467C>T p.R1489= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs911259329; called by muse, mutect2, varscan2
- OR2L13 | c.285A>T p.G95= | Silent (SNP) | VAF 68/361 reads (19%) | called by muse, mutect2, varscan2
- OR4N2 | c.612C>T p.G204= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs781326367, COSV60050293; called by muse, mutect2
- PABPC3 | c.1503C>T p.R501= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- POLN | c.6A>G p.E2= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- QKI | c.534A>G p.L178= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs373262109; called by muse, mutect2, varscan2
- RAG2 | c.945G>A p.K315= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV57559443; called by muse, mutect2, varscan2
- RGL1 | c.1905G>T p.S635= (on ENST00000360851 / NM_001297672.2; = p.S670= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as rs371789837; called by muse, mutect2, varscan2
- ROBO4 | c.882A>G p.G294= | Silent (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- SCML1 | c.942A>G p.L314= (on ENST00000380041 / NM_001037540.3; = p.L287= on NM_006746.6) | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1370869191; called by muse, mutect2, varscan2
- SEC16A | c.5310A>G p.P1770= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- SLCO1B1 | c.963T>C p.N321= | Silent (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- SPG11 | c.6387G>A p.T2129= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs150121550, COSV55990343; called by muse, mutect2
- SPTA1 | c.6651G>T p.V2217= | Silent (SNP) | VAF 36/390 reads (9%) | catalogued as COSV63760322; called by muse, mutect2
- TBX19 | c.543A>G p.V181= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- TFAP2D | c.453C>A p.G151= | Silent (SNP) | VAF 35/187 reads (19%) | called by muse, mutect2, varscan2
- TOX2 | c.1068C>G p.A356= (on ENST00000358131 / NM_001098798.2; = p.A332= on NM_032883.3) | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.1084C>T p.L362= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.50901C>T p.G16967= (on ENST00000591111; = p.G9543= on NM_003319.4) | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- USH2A | c.3343C>T p.L1115= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- WDR72 | c.3045C>A p.S1015= | Silent (SNP) | VAF 35/171 reads (20%) | catalogued as COSV64752073; called by muse, mutect2, varscan2
- WDR76 | c.1806C>T p.H602= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- XKR3 | c.1206A>T p.P402= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8490C>A p.S2830= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV50490374; called by muse, mutect2, varscan2
- ZNF184 | c.1392C>T p.H464= | Silent (SNP) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- ZNF670 | c.1071G>A p.R357= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs1338917096; called by muse, mutect2, varscan2
- ADD2 | c.1742-298A>G | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668374 G>A | 5'Flank (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- AL353804.7 | chrX:73851128 T>C | 3'Flank (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- ANKRD13C | chr1:70355108 G>T | 5'Flank (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- BMP1 | c.731-239T>C | Intron (SNP) | VAF 9/250 reads (4%) | called by muse, mutect2
- DENND10P1 | n.360C>A | RNA (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- DENND10P1 | n.664G>T | RNA (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- DST | c.4296+4521A>T | Intron (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- TTBK1 | c.1986+6353G>C | Intron (SNP) | VAF 51/88 reads (58%) | called by muse, varscan2
- UGT1A6 | c.862-23182G>A | Intron (SNP) | VAF 14/76 reads (18%) | catalogued as rs770873874, COSV59389736; called by muse, mutect2
